Gene-level copy-number profile of tumor specimen RC-B65O-TBP1-A from RC case RC-B65O, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Dead; Primary diagnosis: Prolymphocytic leukemia, T-cell type; Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 65.5 years (23,927 days).
Specimen RC-B65O-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0c1cc858-015c-49ec-ac82-2dc5e4830bc0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B65O-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/c6842389-8710-482b-ad81-e3a33c793d39

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 196; copy number 1: 3,624; copy number 2: 50,837; copy number 3: 3,738; copy number 4: 7.

Homozygous deletions (total copy number 0; autosomes only): 196 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,257,879–38,265,678, 1 gene (within-gene range 0–1): TRGC1.
- chr7:38,276,259–38,311,808, 5 genes (within-gene range 0–1): TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr7:142,666,272–142,802,748, 31 genes (within-gene range 0–1): MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2.
- chr8:34,174,886–34,874,633, 6 genes: AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1.
- chr8:35,254,344–35,256,605, 1 gene (within-gene range 0–2): AC090740.1.
- chr8:38,699,274–40,016,391, 27 genes: AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1.
- chr11:90,017,611–90,087,131, 8 genes: AP004607.6, TRIM49C, AP004607.2, AP004607.4, TRIM64EP, AP004607.5, AP000827.1, UBTFL1.
- chr14:21,887,857–22,008,181, 14 genes: TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19.
- chr14:22,040,594–22,552,156, 100 genes (within-gene range 0–3) (broad region; genes not listed).
- chr22:23,939,998–23,961,195, 3 genes: AP000350.1, AP000350.3, GSTT2B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,624. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
